Gene-level copy-number profile of tumor specimen TCGA-AA-3841-01A from TCGA case TCGA-AA-3841, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.3 years (24,230 days).
Specimen TCGA-AA-3841-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a4acc3d7-b50e-454c-b0c9-e5557e41f950.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3841-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d202f14e-31c0-4eaa-a937-9a9906b7c3e0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 438; copy number 2: 18,465; copy number 3: 27,064; copy number 4: 6,569; copy number 5: 3,895; copy number 6: 174; copy number 7: 3,210.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3841-01A-01D-0903-01): tumor purity 0.65, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,210 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–51,864,798, 903 genes, copy number 7 (broad region; genes not listed).
- chr7:54,185,071–57,275,197, 128 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr20:33,702,758–64,313,132, 788 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
